Somatic mutation profile of tumor specimen C3N-01340-01 (aliquot CPT0094560007) from CPTAC case C3N-01340, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 72.2 years (26,376 days).
Specimen C3N-01340-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bd368db-20c3-4c74-bbe3-294b4010a16e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01340-31 (Blood Derived Normal), aliquot CPT0094620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9c83ad9-687c-48d3-a8ec-df9212398e3a

The open-access MAF lists 126 somatic variants for this specimen: 88 protein-altering or splice-affecting, 22 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 22, Intron 4, 3'UTR 4, Frame Shift Del 3, 5'UTR 3, 5'Flank 3, Nonsense Mutation 3, Splice Region 2, Frame Shift Ins 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.3319C>T p.R1107* | Nonsense Mutation (SNP) | VAF 63/219 reads (29%) | catalogued as rs41309764, CM053346, COSV53027013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV57010300; called by muse, mutect2, varscan2
- AGTR1 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 18/116 reads (16%) | catalogued as rs768866306; called by muse, mutect2, varscan2
- AHSG | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs868152128; called by muse, mutect2
- ART5 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs74708481; called by muse, mutect2, varscan2
- BMPR1A | c.878C>A p.A293E | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64408635; called by muse, mutect2, varscan2
- C17orf75 | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1298207668; called by muse, mutect2, varscan2
- CBY1 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs1329243977; called by muse, mutect2, varscan2
- CD164L2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs138011471; called by muse, mutect2, varscan2
- CLSTN2 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 106/569 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs900952461, COSV71724080; called by mutect2, varscan2
- COL6A2 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs1035008109; called by muse, mutect2
- CRHBP | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.743); catalogued as COSV57188099; called by muse, mutect2
- CWF19L2 | c.2576G>A p.R859K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs776413963; called by muse, mutect2, varscan2
- ERI2 | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs370390087; called by muse, mutect2, varscan2
- FAM184A | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.993); catalogued as rs779916036, COSV100138500; called by muse, mutect2
- FAM221A | c.140C>G p.P47R | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61387743; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 83/554 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.51); catalogued as rs747636311; called by muse, mutect2, varscan2
- ITLN1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs773422900; called by muse, mutect2, varscan2
- KLK12 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 75/624 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs563322085; called by muse, varscan2
- LIN7C | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs908028442, COSV53415225; called by muse, mutect2, varscan2
- LIPI | c.169T>G p.L57V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as rs1414756419; called by muse, mutect2, varscan2
- MEX3C | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as rs533957172; called by muse, mutect2, varscan2
- NES | c.126del p.L43Sfs*67 | Frame Shift Del (DEL) | VAF 91/662 reads (14%) | catalogued as rs1437202416; called by mutect2, pindel, varscan2
- NWD2 | c.2372G>T p.R791I | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.132); catalogued as COSV58754485; called by muse, mutect2, varscan2
- PDZRN3 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761719859, COSV99732423; called by muse, mutect2, varscan2
- PGK2 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs373420238; called by muse, mutect2
- PIK3CG | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.214); catalogued as rs142342118; called by muse, mutect2, varscan2
- PON1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as rs564064745, COSV55931007; called by muse, mutect2, varscan2
- RAB8B | c.489T>A p.F163L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV58490120; called by muse, mutect2, varscan2
- SERHL2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as rs145163201; called by muse, mutect2, varscan2
- SLC4A4 | c.1500C>A p.G500= (on ENST00000264485 / NM_001098484.3; = p.G456= on NM_003759.4) | Splice Region (SNP) | VAF 17/167 reads (10%) | catalogued as rs373128647, COSV52625740; called by muse, mutect2
- TBC1D22A | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs1438584179; called by muse, mutect2, varscan2
- THSD7B | c.3824G>A p.R1275Q (on ENST00000272643; = p.R1273Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs537759315, COSV55689505, COSV55712143; called by muse, mutect2
- TP53 | c.403del p.C135Afs*35 | Frame Shift Del (DEL) | VAF 52/218 reads (24%) | catalogued as COSV52674321, COSV52706302, COSV52827707; called by mutect2, varscan2
- TPSD1 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52974574, COSV99274190; called by muse, varscan2
- UBN1 | c.2171C>G p.S724C | Missense Mutation (SNP) | VAF 12/400 reads (3%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52166040; called by muse, mutect2
- VCAN | c.7040C>T p.A2347V | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs764322664; called by muse, mutect2, varscan2
- WDCP | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as rs754095890, COSV54591692, COSV54592368; called by muse, mutect2, varscan2
- WNK1 | c.4106C>T p.S1369L (on ENST00000315939 / NM_018979.4; = p.S1122L on NM_014823.3) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1466139017; called by muse, mutect2, varscan2
- ZFYVE21 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs764421307; called by muse, mutect2
- ZNF831 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV64038387; called by muse, mutect2, varscan2
- ACVR1C | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- ADAMTS15 | c.1848C>G p.C616W | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRA2 | c.2283G>C p.E761D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ADRA2B | c.182T>A p.V61E | Missense Mutation (SNP) | VAF 80/541 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL772337.1 | n.857+6C>T | Splice Region (SNP) | VAF 38/334 reads (11%) | called by muse, mutect2, varscan2
- AMER2 | c.405dup p.R136Afs*127 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- APOL4 | c.931G>T p.D311Y (on ENST00000352371 / NM_145660.2; = p.D308Y on NM_030643.4) | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ATP13A1 | c.2790G>C p.Q930H | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- CDIP1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDRT1 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CHEK2 | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DEFB123 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- DNAH14 | c.7934C>G p.A2645G (on ENST00000445597; = p.A3448G on NM_001367479.1) | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.419); called by muse, mutect2
- DSCAM | c.4204G>T p.G1402* | Nonsense Mutation (SNP) | VAF 49/310 reads (16%) | called by muse, mutect2, varscan2
- EFHD1 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ERH | c.7C>G p.H3D | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- FLG | c.7082G>C p.R2361P | Missense Mutation (SNP) | VAF 57/469 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- GAREM2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GPCPD1 | c.1751G>T p.C584F | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- GPR160 | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFT122 | c.3142C>A p.H1048N (on ENST00000348417 / NM_052989.3; = p.H989N on NM_018262.4) | Missense Mutation (SNP) | VAF 83/850 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGKV3-15 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 71/1462 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- IGLV1-47 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- LYN | c.809C>A p.T270N | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- LZTR1 | c.914_918del p.N305Tfs*9 | Frame Shift Del (DEL) | VAF 41/309 reads (13%) | called by mutect2, pindel, varscan2
- MASP1 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 37/388 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- MYL9 | c.74T>C p.M25T | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- MYO1F | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 85/501 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBAS | c.6118G>A p.A2040T | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- NPY1R | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10X1 | c.794T>A p.I265K | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- OTC | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PACRG | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2
- PAXBP1 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); called by muse, mutect2
- PLEKHH3 | c.800_801dup p.V268Rfs*20 | Frame Shift Ins (INS) | VAF 16/110 reads (15%) | called by mutect2, pindel
- POM121 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- PPP4R1 | c.159G>T p.K53N (on ENST00000400556 / NM_001042388.3; = p.K36N on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SAE1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SIRT7 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 67/524 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRCAP | c.7085A>T p.E2362V | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2
- TNIK | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTN | c.88190A>G p.D29397G (on ENST00000591111; = p.D21973G on NM_003319.4) | Missense Mutation (SNP) | VAF 35/171 reads (20%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC5D | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- VPS13D | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZEB2 | c.3516G>T p.M1172I | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF527 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF714 | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAMTS1 | c.1926G>A p.A642= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs371016638; called by muse, mutect2, varscan2
- CDH17 | c.2085G>A p.Q695= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as rs758016278; called by muse, mutect2, varscan2
- DRC1 | c.259C>T p.L87= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- EPHB4 | c.477G>A p.V159= | Silent (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- EPPK1 | c.2106C>G p.L702= | Silent (SNP) | VAF 26/636 reads (4%) | called by muse, mutect2
- FUS | c.375C>T p.P125= | Silent (SNP) | VAF 85/553 reads (15%) | called by muse, mutect2, varscan2
- GMCL1 | c.117G>A p.A39= | Silent (SNP) | VAF 14/366 reads (4%) | catalogued as rs1458281488, COSV57000646; called by muse, mutect2
- GPR156 | c.817C>T p.L273= | Silent (SNP) | VAF 80/602 reads (13%) | called by muse, mutect2, varscan2
- IGF2R | c.1488G>A p.E496= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs772103874; called by muse, mutect2, varscan2
- LRRK1 | c.5964C>T p.G1988= | Silent (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- MCM3AP | c.1659G>C p.L553= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV99387410; called by muse, mutect2
- OTX1 | c.84C>A p.S28= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2
- PCDH10 | c.1059C>T p.D353= | Silent (SNP) | VAF 50/322 reads (16%) | called by muse, mutect2, varscan2
- PLXNB1 | c.4134C>T p.P1378= | Silent (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- PRRC2C | c.5799G>A p.Q1933= (on ENST00000367742; = p.Q1931= on NM_015172.4) | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100145060; called by muse, mutect2, varscan2
- RACGAP1 | c.1683C>G p.A561= | Silent (SNP) | VAF 34/263 reads (13%) | called by muse, mutect2, varscan2
- RECQL5 | c.1320G>A p.V440= | Silent (SNP) | VAF 111/729 reads (15%) | called by muse, mutect2, varscan2
- SLC25A30 | c.768A>G p.E256= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as rs746275810; called by muse, mutect2, varscan2
- SOX9 | c.892C>T p.L298= | Silent (SNP) | VAF 49/463 reads (11%) | called by muse, mutect2
- TERT | c.1644G>A p.L548= | Silent (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- ZFHX3 | c.7299G>A p.A2433= | Silent (SNP) | VAF 52/404 reads (13%) | catalogued as rs767810299, COSV51708267; called by muse, mutect2, varscan2
- ZFYVE1 | c.2304C>T p.F768= | Silent (SNP) | VAF 14/384 reads (4%) | called by muse, mutect2
- ATG4B | chr2:241637591 G>A | 5'Flank (SNP) | VAF 56/383 reads (15%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.-29G>A | 5'UTR (SNP) | VAF 80/474 reads (17%) | catalogued as COSV100666982; called by muse, mutect2, varscan2
- CCDC180 | c.3981-11G>C | Intron (SNP) | VAF 32/178 reads (18%) | called by muse, mutect2, varscan2
- FAM155A | c.*2G>A | 3'UTR (SNP) | VAF 9/45 reads (20%) | catalogued as rs367986126, COSV101027155; called by muse, mutect2, varscan2
- FCMR | c.37+465G>T | Intron (SNP) | VAF 13/75 reads (17%) | catalogued as rs998748281, COSV65568803; called by muse, mutect2, varscan2
- HSD11B2 | c.266-56G>A | Intron (SNP) | VAF 46/395 reads (12%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-43T>A | Intron (SNP) | VAF 42/194 reads (22%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.67G>C | RNA (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- NKAIN4 | c.*49G>A | 3'UTR (SNP) | VAF 25/205 reads (12%) | catalogued as rs1214227675; called by muse, mutect2, varscan2
- RBAK | c.-30G>T | 5'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- RNU6-389P | chr7:55682795 A>G | 5'Flank (SNP) | VAF 20/120 reads (17%) | catalogued as rs778107384; called by muse, varscan2
- RPS23 | c.*870A>G | 3'UTR (SNP) | VAF 20/122 reads (16%) | called by mutect2, varscan2
- SNORD116-17 | chr15:25088002 C>G | 3'Flank (SNP) | VAF 18/204 reads (9%) | called by muse, varscan2
- STPG4 | c.-2C>T | 5'UTR (SNP) | VAF 56/241 reads (23%) | called by muse, mutect2, varscan2
- TCF20 | c.*86G>A | 3'UTR (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- ZNF41 | chrX:47483763 G>C | 5'Flank (SNP) | VAF 22/155 reads (14%) | catalogued as rs1422309829; called by muse, mutect2, varscan2
